TCGA case TCGA-32-2638 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: St. Joseph's Hospital (AZ). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1b25795e-69ad-47fd-bb2f-94ff0910fae1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Dead; Days to death: 766 days (2.1 years).

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 67.5 years (24,658 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 26 days; Days to treatment end: 68 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 26 days; Days to treatment end: 68 days; Treatment dose: 190 mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Clinical Trial; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 133 days; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 110 days; Days to treatment end: 114 days; Treatment dose: 380 mg/day; Route of administration: Oral.

Follow-up (6 entries)
- Days to follow up: 224 days; Disease response: Tumor Free.
- Days to follow up: 644 days (1.8 years); Disease response: With Tumor.
- Days to follow up: 766 days (2.1 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.
- ECOG performance status: 0; Timepoint: Prior to Adjuvant Therapy.
- Follow-up contact recording only the day: day 581.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-32-2638-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-32-2638-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 20.
  Slide TCGA-32-2638-01A-01-TS1: Section location: Top; Percent tumor cells: 82; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 15.
- Sample TCGA-32-2638-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: Tumor free; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Bevacizumab or placebo RTOG 0825.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Follow-up form 2: Performance status timing: Post-Adjuvant Therapy.
- Follow-up form 3: Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 766 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 766 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 766 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-32-2638-01A-01D-0911-01): tumor purity 0.83, ploidy 1.99, whole-genome doublings 0.
